Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1DQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1DQ-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Adenocarcinoma, serous, NOS 8441/3

Site Code: endometrium C54.1

TSS Name/##: ---

1/12

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries (
- 2: SP: Omentum
- 3: SP: Right peri-aortic lymph node
- 4: SP: Left peri-aortic lymph node
- 5: SP: Left external iliac lymph node
- 6: SP: Left common iliac lymph node
- 7: SP: Left obturator lymph node
- 8: SP: Left hypogastric lymph node
- 9: SP: Right external iliac lymph node
- 10: SP: Right obturator lymph node

DIAGNOSIS:

- 1) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- PAPILLARY SEROUS CARCINOMA OF THE ENDOMETRIUM ARISING IN AN ATROPHIC POLYP.
- THE TUMOR INVADES THROUGH MORE THAN HALF OF MYOMETRIAL THICKNESS (MAXIMAL TUMOR INVASION IS 18 MM IN AN AREA WHERE THE TOTAL MYOMETRIAL THICKNESS MEASURES 22 MM).
- VASCULAR INVASION IS PRESENT.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- THE ENDOMETRIUM AWAY FROM SEROUS CARCINOMA SHOWS COMPLEX HYPERPLASIA WITH ATYPIC.
- THE COMPLEX ATYPICAL HYPERPLASIA INVOLVES AN ENDOMETRIAL POLYP.
- THE REST OF THE MYOMETRIUM SHOWS LEIOMYOMA(S).
- THE SEROSA IS UNREMARKABLE.
- BOTH OVARIES AND FALLOPIAN TUBES ARE BENIGN.
- 2) OMENTUM; OMENTECTOMY:
- BENIGN FIBROADIPOSE TISSUE.
- 3) LYMPH NODE, RIGHT PERICOLIC; DISSECTION:
- FOUR BENIGN LYMPH NODES (0/4).

** Continued on next page **

[page 2 of 2]
TSS Name/##

- Page 2 of 6
- 4) LYMPH NODE, LEFT PERIAORTIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 5) LYMPH NODE, LEFT EXTERNAL ILIAC; DISSECTION:
- METASTATIC CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).
- 6) LYMPH NODE, LEFT COMMON ILIAC; DISSECTION:
- METASTATIC CARCINOMA IN THREE OF SIX LYMPH NODES (3/6).
- 7) LYMPH NODE, LEFT OBTURATOR; EXCISION;
- METASTATIC CARCINOMA IN ONE OF TWO LYMPH NODES (1/2).
- 8) LYMPH NODE, LEFT HYPOGASTRIC; EXCISION:
- METASTATIC CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).
- 9) LYMPH NODE, RIGHT EXTERNAL ILIAC; DISSECTION:
- ONE BENIGN LYMPH NODE (0/1).
- 10) LYMPH NODE, RIGHT OBTURATOR; DISSECTION:
- FIVE BENIGN LYMPH NODES (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 47101546-2127-4926-845f-36800daa1677 (TCGA-AP-A1DQ.F5983E58-F466-42CF-8905-B942D2BDF702.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).